Surgical pathology report (de-identified scan), TCGA case TCGA-T2-A6X2, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site St. University of Colorado Denver, specimen TCGA-T2-A6X2-01A (Primary Tumor).

[page 1 of 4]
Name: [REDACTED]

Gender: M [REDACTED]

Unit#: [REDACTED]

Histology Report

Date:

Status Final

Document Id:

Ordered by:

Clinician:

Accession Number:

Microscopic Diagnosis:

A) Lymph nodes, superficial zone 2 of left neck, dissection:

- Six lymph nodes and associated soft tissue, negative for carcinoma (0/6)

B) Left mandible, mandibulectomy:

- Invasive well differentiated keratinizing squamous cell carcinoma (4.2 cm)

- Carcinoma invades into mandibular bone

- Perineural invasion is identified

- Microscopic focus of carcinoma is present on section of posterior bony margin; all other sampled margins are negative for carcinoma

- See Comments and Macroscopic and Microscopic Summary

C) "True posterior margin (RNT)," excision:

- Negative for carcinoma (benign squamous mucosa, fibroadipose tissue and skeletal muscle with al chronic inflammation)

D) Left alveolar nerve, biopsy:

- Negative for carcinoma (benign nerve tissue)

E) True deep posterior margin, excision:

- Negative for carcinoma (benign fibroadipose tissue, skeletal muscle and nerve tissue)

F) Lymph nodes, zone 1 of right neck, dissection:

- Six lymph nodes and associated soft tissue, negative for carcinoma (0/6)

G) Lymph nodes, zones 2 and 3 of right neck, dissection:

- Seven lymph nodes and associated soft tissue, negative for carcinoma (0/7)

H) Lymph nodes, zone 1 of left neck, dissection:

- Eleven lymph nodes and associated soft tissue, negative for carcinoma (0/11)

I) Lymph nodes, zones 2 and 3 of left neck, dissection:

- Twenty-three lymph nodes and associated soft tissue, negative for carcinoma (0/23)

J) Teeth numbers 5, 6, 23, 10 and 26, extraction:

- Teeth (gross diagnosis)

Comments:

The carcinoma cells are strongly (3+) and diffusely (almost 100%) positive for EGFR by immunohistochemistry.

HPV studies have been ordered and will be reported separately.

has reviewed key slides of this case and concurs with the diagnosis.

Clinical History:

Printed By:

ICD-O-3
Carcinoma, squamous cell
Keratinizing NOS 8071/3
Site C64
Alveolar ridge mucosa NOS
path C63.9
Mandible C41.1
8/13/13

Unit#:

Print Date:

or Malignancy History		
use is (circle):		

[page 2 of 4]
An: year-old male with squamous cell carcinoma of the left mandible.

MACROSCOPIC AND MICROSCOPIC SUMMARY

Specimen: Mandible (partial)

Procedure: Segmental mandibulectomy

Specimen Integrity: Intact

Specimen Laterality: Left

Tumor Site: Mandible

Tumor Focality: Single focus

Tumor Size: Greatest dimension: 4.2 cm (additional dimensions: 2.6 x 1.5 cm)

Histologic Type: Squamous cell carcinoma, conventional, keratinizing

Histologic Grade: G1: Well differentiated

Margins:

Focally positive for carcinoma (Specify margin: microscopic focus involving posterior bony margin)

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Present

Pathologic Staging (pTNM):

Primary Tumor (pT)

pT3: Tumor more than 4 cm in greatest dimension

Regional Lymph Nodes (pN):

pN0: No regional lymph node metastasis

(Specify: number examined: 53; number involved: 0)

Distant Metastasis (pM)

Not Applicable

Gross Description:

Received are ten specimens, labeled with the patient's name and medical record number.

A) Fresh, labeled "left superficial zone 2 lymph nodes," are two fragments of red-tan fatty tissue, measuring 1.8 x 1 x 0.4 cm and 1.4 x 0.7 x 0.5 cm. The larger fragment is bisected and entirely submitted for frozen sectioning, and the remnant is submitted for permanent in cassette (FSA1). The smaller fragment is bisected and entirely submitted entirely for frozen sectioning, and the remnant is submitted for permanent in cassette (FSA2).

B) Fresh, labeled "left composite resection," is a partial resection of mandible, measuring 6.7 cm in length and 2.5 x 1.3 cm in average cross sectional area, with attached muscle and soft tissue. There is a single long stitch designated as "anterior", a double long stitch is designated as "posterior", a single short stitch designated as "lateral", and a double short stitch which is designated as "medial". At the anterior aspect of the specimen there is single remaining tooth with a metal cap. The overlying muscle and soft tissue is yellow-white and fibrotic. On the medial aspect of the specimen there is an ulcerated, friable, tan-pink tumor, measuring 4.2 x 2.6 x 1.5 cm. A rim of mucosal tissue surrounds the lesion, and the soft tissue margins appear negative for tumor on gross examination. The bony margins are viable-appearing without evidence of necrosis or tumor on gross examination. The specimen's surgical margins are inked as follows:

Lateral = Green

Medial = Blue

Posterior = Red

Anterior = Orange

Representative sections are then submitted as follows:

(B1-B2) Bone underlying tumor, following decalcification

(B3) Anterior lateral mucosal margin

(B4-B8) Full thickness sections of tumor, every other section

(B9) Tumor with posterolateral margin

(B10) Tumor with posteromedial margin

(B11) Tumor with anteromedial margin

(B12) Anterior soft tissue margin

(B13) Inferomedial soft tissue margin

(B14) Inferolateral soft tissue margin

(B15) Anterior bony margin, en face, following decalcification

(B16) Posterior bony margin, en face, following decalcification

Pt. Name: [REDACTED]

Unit#: [REDACTED]

Printed By: [REDACTED]

Print Date: [REDACTED]

Page 2 of 4

[page 3 of 4]
G) Fresh, labeled "true posterior margin (RNT)," is a fragment of tissue, 2.5 x 0.5 x 0.3 cm. The specimen is submitted entirely for frozen section and the remnant is submitted for permanent in cassette (FSC1).

D) Fresh, labeled "left alveolar nerve," is a fragment of soft tissue, 0.5 x 0.3 x 0.2 cm. The specimen is submitted entirely for frozen section and the remnant is submitted for permanent in cassette (FSD1).

E) Fresh, labeled "true deep posterior margin," is a fragment of red soft tissue, 1 x 1 x 0.5 cm. The specimen is bisected and submitted entirely for frozen section and the remnant is submitted for permanent in cassette (FSE1).

F) Formalin, labeled "right neck dissection zone 1," is a single fragment of yellow adipose tissue, 6.0 x 3.5 x 2.2 cm, which includes multiple palpable lymph nodes. Representative sections are submitted as follows:

- (F1) Three candidate lymph nodes
- (F2) One candidate lymph node, bisected
- (F3) One candidate lymph node, bisected
- (F4-F5) Representative adipose tissue

G) Formalin, labeled "right neck dissection zone 2 and 3 (stitch on zone 2)," is a single fragment of yellow-tan fibroadipose tissue, 6.8 x 3.8 x 2.0 cm, with a single black stitch designating the zone 2 location. There is a single palpable lymph node within zone 2 and multiple palpable lymph nodes within zone 3. Representative sections are submitted as follows:

- (G1) One candidate lymph node, bisected, zone 2
- (G2) Two candidate lymph nodes, zone 3
- (G3) One candidate lymph node, bisected, zone 3
- (G4-G5) Representative adipose tissue, zone 3

H) Formalin, labeled "left neck dissection, zone 1," is a single fragment of yellow-brown fibroadipose tissue, 9.8 x 4.5 x 2.0 cm. There are multiple palpable lymph nodes within the specimen. Representative sections are submitted as follows:

- (H1) Six candidate lymph nodes
- (H2) One candidate lymph node, bisected
- (H3) One candidate lymph node, bisected
- (H4) One candidate lymph node, bisected
- (H5) One candidate lymph node
- (H6) One candidate lymph node, bisected
- (H7) One candidate lymph node
- (H8-H10) Representative adipose tissue

I) Formalin, labeled "left neck dissection, zone 2 and 3 (stitch on zone 2)," is a single fragment of yellow-brown fibroadipose tissue, 9.7 x 3 x 1.5 cm, with a single stitch designating zone 2. There are multiple palpable lymph nodes within zone 2 and zone 3. Representative sections are submitted as follows:

- (I1) Three candidate lymph nodes, zone 2
- (I2) One candidate lymph node, bisected, zone 2
- (I3-I4) I3 and I4 together equal one candidate lymph node, bisected, zone 2
- (I5) Five candidate lymph nodes, zone 3
- (I6) Six candidate lymph nodes, zone 3
- (I7) One candidate lymph node, bisected, zone 3
- (I8) Two candidate lymph nodes, zone 3
- (I9-I10) Representative adipose tissue, zone 3

J) Formalin, labeled "teeth #5, 6, 23, 10, 26," are five extracted teeth, 4.5 x 3 x 0.5 cm in aggregate. A digital photograph is taken. No tissue is submitted for histology.

Intraoperative Consultation:
Frozen section consultation

(FSA1): Lymph node tissue, negative for carcinoma

Pt. Name: [REDACTED]

Printed By: [REDACTED]

Unit#: [REDACTED]

Print Date: [REDACTED]

Page 3 of 4

[page 4 of 4]
(FSA2): Lymph node tissue, negative for carcinoma

Time received:
Time reported:
Total time: 19 minutes

(C): Negative for carcinoma
(FSD): Negative for carcinoma
(FSE): Negative for carcinoma

Time received:
Time reported:
Total time:

Interpreted by:

Interpreted by:

___ ELECTRONICALLY SIGNED ___

Pathologist

Date: ___

Some tests used in this case were developed in and their performance characteristics determined by the

The procedures and reagents have been validated by evaluation of both negative and positive controls. This testing has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. Test results are used for clinical purposes. They should not be regarded as investigational or for research. The is accredited by the College of American Pathologists and is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

certify that (1) all services on this form were rendered and are hereby approved for billing, (2) all specimens/slides have been examined/reviewed, (3) the medical record has been documented for these services, and (4) the rendering of the services and the documentation in the medical record are in accordance with guidelines."

The following special evaluations were performed on this specimen. Please refer to the Microscopic Description or Comment section(s).

Stain
Specimen
Block
Level
Tissue

EGFr	B	6	2	Bone
HPV	B	6	3	Bone
CMOCO-ENT		B	6	4 Bone
Recut	B	6	5	Bone
EGFr	B	6	6	Bone

The following cases, on this patient, were collected on the same day as this case.

Pt. Name

Unit#:

Printed By:

Print Date:

Page 4 of 4

Source: NCI Genomic Data Commons file b65cd0e3-73ec-461a-99e5-6a33cf3473cb (TCGA-T2-A6X2.543B4034-C428-4160-B8E3-02F5A79BD91B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).